Somatic mutation profile of tumor specimen ALCH-B2VL-TTP1-A (aliquot ALCH-B2VL-TTP1-A-1-0-D-A78Q-36) from ALCHEMIST case ALCH-B2VL, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Pleomorphic carcinoma; Age at diagnosis: 65.8 years (24,051 days).
Specimen ALCH-B2VL-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec84717b-8284-4771-994f-8ae370b5b36c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2VL-NB1-A (Blood Derived Normal), aliquot ALCH-B2VL-NB1-A-1-0-D-A78Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/710e396e-99be-49ba-aff9-9eef1fb4ecf0

The open-access MAF lists 51 somatic variants for this specimen: 42 protein-altering or splice-affecting, 4 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 4, Frame Shift Del 3, RNA 3, Nonsense Mutation 2, Intron 1, 3'Flank 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTN1 | c.973C>G p.P325A | Missense Mutation (SNP) | VAF 15/301 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV51992257; called by muse, mutect2
- AGBL1 | c.3296A>C p.K1099T | Missense Mutation (SNP) | VAF 25/191 reads (13%) | PolyPhen benign (0); catalogued as COSV66855424; called by muse, mutect2, varscan2
- ALG2 | c.144G>C p.K48N | Missense Mutation (SNP) | VAF 34/282 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs767971393; called by muse, mutect2
- ATXN1 | c.358T>C p.Y120H | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs763470838; called by muse, varscan2
- CDC42BPB | c.4798G>A p.G1600S | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.568); catalogued as rs1323922137, COSV100775056; called by muse, mutect2, varscan2
- DBH | c.986G>A p.R329H | Missense Mutation (SNP) | VAF 51/405 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV55042460; called by muse, mutect2, varscan2
- DOP1B | c.3241C>G p.R1081G | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV67692310; called by muse, mutect2, varscan2
- HOXA4 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs773957594; called by mutect2, varscan2
- KCNT1 | c.2983G>A p.E995K (on ENST00000488444; = p.E1014K on NM_020822.3) | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.194); catalogued as rs745590718; called by muse, mutect2
- LRCH4 | c.1180C>T p.R394W | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as rs748921886, COSV59643994; called by muse, mutect2, varscan2
- MROH8 | c.1462G>A p.A488T | Missense Mutation (SNP) | VAF 25/279 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.983); catalogued as COSV99456830; called by muse, mutect2
- NLRP3 | c.2188G>C p.G730R | Missense Mutation (SNP) | VAF 118/595 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.163); catalogued as COSV100275300; called by muse, varscan2
- PDZD3 | c.1061-5C>T | Splice Region (SNP) | VAF 22/145 reads (15%) | catalogued as rs780190434; called by muse, mutect2, varscan2
- PIF1 | c.1435G>T p.A479S | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); catalogued as rs753026538; called by muse, mutect2
- RAI1 | c.868C>T p.Q290* | Nonsense Mutation (SNP) | VAF 44/471 reads (9%) | catalogued as rs771803841; called by muse, mutect2
- RIMS1 | c.4615A>G p.M1539V | Missense Mutation (SNP) | VAF 81/779 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as COSV53489310; called by muse, mutect2, varscan2
- SZT2 | c.1486_1487del p.T496Afs*22 | Frame Shift Del (DEL) | VAF 16/160 reads (10%) | catalogued as rs780204992; called by pindel, varscan2
- AC104452.1 | c.974C>G p.A325G | Missense Mutation (SNP) | VAF 44/297 reads (15%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- CD200 | c.272A>G p.K91R (on ENST00000473539 / NM_001004196.3; = p.K66R on NM_005944.7 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/441 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- CDHR2 | c.1630G>C p.E544Q | Missense Mutation (SNP) | VAF 89/358 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- CDK5RAP1 | c.107T>G p.L36R | Missense Mutation (SNP) | VAF 70/403 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEP290 | c.1783G>A p.D595N | Missense Mutation (SNP) | VAF 106/582 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, varscan2
- CEP290 | c.1723G>A p.E575K | Missense Mutation (SNP) | VAF 91/436 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.036); called by muse, varscan2
- CRIM1 | c.2134A>G p.T712A | Missense Mutation (SNP) | VAF 10/348 reads (3%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); called by muse, mutect2
- CSRP1 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2
- EPS8L1 | c.2146G>A p.G716S (on ENST00000201647 / NM_133180.3; = p.G589S on NM_017729.3) | Missense Mutation (SNP) | VAF 57/266 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ID1 | c.191T>G p.V64G | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- ILDR2 | c.1066A>G p.M356V | Missense Mutation (SNP) | VAF 51/528 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- LRP1 | c.11570A>C p.H3857P | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MET | c.3027_3028+5del p.X1009_splice | Splice Site (DEL) | VAF 63/336 reads (19%) | called by mutect2, pindel, varscan2
- MYH15 | c.4308G>T p.E1436D | Missense Mutation (SNP) | VAF 10/293 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.46); called by muse, mutect2
- NUP54 | c.374del p.S125Lfs*52 | Frame Shift Del (DEL) | VAF 50/460 reads (11%) | called by mutect2, varscan2
- ORAI3 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 8/175 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PARVG | c.606T>G p.F202L | Missense Mutation (SNP) | VAF 48/237 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- PLA1A | c.104del p.C35Sfs*32 | Frame Shift Del (DEL) | VAF 54/292 reads (18%) | called by mutect2, pindel, varscan2
- PLK2 | c.1946A>T p.D649V | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); called by muse, mutect2
- PPARGC1A | c.2344T>A p.S782T | Missense Mutation (SNP) | VAF 63/349 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- SLU7 | c.1364G>C p.C455S | Missense Mutation (SNP) | VAF 25/249 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM132C | c.91G>T p.E31* | Nonsense Mutation (SNP) | VAF 6/46 reads (13%) | called by muse, varscan2
- TPTE | c.70C>A p.Q24K | Missense Mutation (SNP) | VAF 30/471 reads (6%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0.041); called by muse, mutect2
- TRMO | c.887C>G p.A296G | Missense Mutation (SNP) | VAF 23/215 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ZNF529 | c.417C>A p.F139L | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- LSMEM2 | c.328C>T p.L110= | Silent (SNP) | VAF 29/152 reads (19%) | called by muse, mutect2, varscan2
- ROBO2 | c.3054A>G p.P1018= | Silent (SNP) | VAF 23/153 reads (15%) | called by muse, mutect2, varscan2
- RPE65 | c.120C>A p.G40= | Silent (SNP) | VAF 16/547 reads (3%) | called by muse, mutect2
- TSC2 | c.4947C>T p.V1649= | Silent (SNP) | VAF 28/265 reads (11%) | catalogued as COSV99032335; called by muse, mutect2, varscan2
- C11orf40 | n.33A>C | RNA (SNP) | VAF 16/404 reads (4%) | called by muse, mutect2
- HSP90AA4P | n.2133A>T | RNA (SNP) | VAF 33/296 reads (11%) | called by muse, mutect2, varscan2
- PCAT19 | n.1209T>C | RNA (SNP) | VAF 31/156 reads (20%) | called by muse, mutect2, varscan2
- PDE6B | c.927+17G>C | Intron (SNP) | VAF 16/71 reads (23%) | catalogued as COSV55327869; called by muse, mutect2, varscan2
- RNY3P11 | chr6:109306099 C>T | 3'Flank (SNP) | VAF 24/165 reads (15%) | called by muse, mutect2, varscan2
